Somatic mutation profile of tumor specimen TCGA-HC-8258-01B (aliquot TCGA-HC-8258-01B-05D-2298-08) from TCGA case TCGA-HC-8258, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.7 years (20,703 days).
Specimen TCGA-HC-8258-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 492cd7ff-d747-4167-b530-3c34199095b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-8258-10A (Blood Derived Normal), aliquot TCGA-HC-8258-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da5d7e48-10ea-4ecd-a2c8-2fe946173652

The open-access MAF lists 10 somatic variants for this specimen: 10 protein-altering or splice-affecting.
By variant classification: Missense Mutation 10.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 21/387 reads (5%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV61652724, COSV61652960, COSV61653269; called by muse, mutect2
- CCDC144A | c.1019A>G p.N340S | Missense Mutation (SNP) | VAF 16/382 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV100138673; called by muse, mutect2
- ENTPD7 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs1013401025, COSV65112431; called by muse, mutect2, varscan2
- MTHFD1 | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.671); catalogued as rs1437397220, COSV53701640; called by muse, mutect2
- NTNG1 | c.1471G>C p.A491P (on ENST00000370068 / NM_001113226.3; = p.A390P on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as COSV100903503, COSV64276985; called by muse, mutect2
- NTNG1 | c.1472C>A p.A491E (on ENST00000370068 / NM_001113226.3; = p.A390E on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.25); catalogued as COSV100903505; called by muse, mutect2, varscan2
- OR4C6 | c.274C>G p.L92V | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.354); catalogued as COSV58604485; called by muse, mutect2
- ZFP69 | c.731A>C p.K244T | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV65529120; called by muse, mutect2
- CEACAM20 | c.1466C>G p.T489S | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.061); called by muse, mutect2
- FANCA | c.256T>A p.Y86N | Missense Mutation (SNP) | VAF 16/236 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.015); called by muse, mutect2
